Surgical pathology report (de-identified scan), TCGA case TCGA-63-7023, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Ontario Institute for Cancer Research, specimen TCGA-63-7023-01A (Primary Tumor).

[page 1 of 5]
A description for each data field can be found in the 'Data description' worksheet (yellow tab).

Sample Collection Details

Sample Number	Sample Type
	BUFFY
	TUMOUR

[page 2 of 5]
					Histology and staging			
Sample Preparation	Site of Tissue	Year of Sample Collection	Age at Sample Collection (yrs)	Sample Comments	Days to Procedure Date	Days to Diagnosis	Type of Procedure	Site of Primary (Histology)
FF	left lower l					3	21 RESECT	LLL
FF						0	18 RESECT	LLL

[page 3 of 5]
Tumour Size (cm)	Histology	Grade/Differentiation	Pathologic al T	Pathologic al N	Clinical M	VALCSG Stage	Histology Comments	Slide URL
2.1		7 III	T1	N1	M0		Left inter lobar lymph r	
2.1		7 III	T1	N1	M0		Left inter lobar lymph r	

[page 4 of 5]
node station 11: Metastatic squamous cell carcinoma. Left lower lobe wedge upper lobe: Squamous cell

[page 5 of 5]
carcinoma with squamous cell carcinoma in-situ extending very close to resection margin.

Source: NCI Genomic Data Commons file 280d469a-489b-4f15-8412-94f0fc8b8037 (TCGA-63-7023.ED241575-C4E4-44C8-9692-428B82BE431D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).